Somatic mutation profile of tumor specimen 4533a2d6-e850-43f3-9c44-621c07 (aliquot 4533a2d6-e850-43f3-9c44-621c07_D6_1) from CPTAC case 11BR055, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 56.2 years (20,531 days).
Specimen 4533a2d6-e850-43f3-9c44-621c07: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4be555e7-2dc4-40fa-a542-a4ccf4864098.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 284b7f89-0dfe-4333-b05e-988a60 (Blood Derived Normal), aliquot 284b7f89-0dfe-4333-b05e-988a60_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/434e3503-0ae1-4c1e-ac06-ff471fa4f016

The open-access MAF lists 95 somatic variants for this specimen: 61 protein-altering or splice-affecting, 18 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 18, Intron 9, Frame Shift Del 7, 3'UTR 4, In Frame Del 3, RNA 2, 5'UTR 1, Frame Shift Ins 1, Splice Region 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERCC2 | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 22/99 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV101228746, COSV67263243; called by muse, mutect2, varscan2
- SF3B1 | c.2098A>G p.K700E | Missense Mutation (SNP) | VAF 32/147 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559063155, COSV59205318, COSV59216586; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARMC3 | c.461C>G p.P154R | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53063978; called by muse, mutect2, varscan2
- FAM135B | c.2743C>T p.Q915* | Nonsense Mutation (SNP) | VAF 43/237 reads (18%) | catalogued as COSV52714371; called by muse, mutect2, varscan2
- KCNJ6 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV55710122; called by muse, mutect2, varscan2
- KIF5A | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 73/297 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.302); catalogued as rs778095192, COSV54056907; called by muse, mutect2, varscan2
- LGALS12 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.609); catalogued as rs1406382454; called by muse, mutect2, varscan2
- MYO5C | c.5066G>A p.R1689H | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759174437; called by muse, mutect2, varscan2
- NDUFB6 | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100598285; called by muse, mutect2, varscan2
- OR2T6 | c.673G>T p.V225L | Missense Mutation (SNP) | VAF 107/295 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV63216855; called by muse, mutect2, varscan2
- PCDHGA8 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 23/239 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53896288; called by muse, mutect2
- PTBP1 | c.905C>T p.P302L (on ENST00000349038 / NM_031991.4; = p.P328L on NM_002819.5) | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs746526932; called by muse, mutect2, varscan2
- RAD9B | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.003); catalogued as COSV62826072; called by muse, mutect2, varscan2
- SETD1A | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 63/229 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1170883733; called by muse, mutect2, varscan2
- SMAD4 | c.788-1G>C p.X263_splice | Splice Site (SNP) | VAF 37/319 reads (12%) | catalogued as COSV61685479; called by muse, mutect2, varscan2
- STK3 | c.508C>G p.Q170E | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV69222407; called by muse, mutect2, varscan2
- TMPRSS11A | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV100602621; called by muse, mutect2, varscan2
- VWA5B1 | c.3302C>T p.T1101I (on ENST00000375079; = p.T1096I on NM_001039500.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1223276579; called by muse, mutect2
- ABCC1 | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- ADAM22 | c.883A>G p.T295A | Missense Mutation (SNP) | VAF 56/263 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADRA1D | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AIMP2 | c.82C>G p.P28A | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.022); called by muse, mutect2
- ALMS1 | c.2056G>T p.G686C | Missense Mutation (SNP) | VAF 36/289 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); called by mutect2, varscan2
- ANO4 | c.633_640del p.R211Sfs*2 (on ENST00000392977 / NM_001286615.2; = p.R176Sfs*2 on NM_178826.4) | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | called by mutect2, pindel, varscan2
- ARHGAP9 | c.1729T>C p.Y577H (on ENST00000393797 / NM_001319850.2; = p.Y558H on NM_032496.4) | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATAD3C | c.163A>G p.T55A | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CACNA1S | c.1627A>G p.T543A | Missense Mutation (SNP) | VAF 63/425 reads (15%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CDH4 | c.2128G>T p.V710L | Missense Mutation (SNP) | VAF 78/287 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CDKL4 | c.904G>A p.G302R | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHD2 | c.542T>A p.V181D | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.063); called by muse, varscan2
- CKMT2 | c.782T>C p.I261T | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- COL4A5 | c.4222C>T p.P1408S | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- CPSF1 | c.2713_2715del p.K905del | In Frame Del (DEL) | VAF 46/108 reads (43%) | called by pindel, varscan2
- DSC3 | c.21_37del p.S9Lfs*16 | Frame Shift Del (DEL) | VAF 52/162 reads (32%) | called by mutect2, pindel, varscan2
- DSG2 | c.3262T>A p.F1088I | Missense Mutation (SNP) | VAF 59/335 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ESPNL | c.2147T>G p.I716S | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAM229A | c.16_30del p.T6_G10del | In Frame Del (DEL) | VAF 12/55 reads (22%) | called by mutect2, pindel, varscan2
- IDH3B | c.469A>C p.N157H | Missense Mutation (SNP) | VAF 100/392 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- IGSF6 | c.515C>A p.A172D | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- INPPL1 | c.1039_1068del p.R347_W356del | In Frame Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- KDM2B | c.15A>T p.Q5H | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- LMAN2L | c.770C>G p.T257S | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYLIP | c.119A>T p.D40V | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEURL4 | c.994A>G p.N332D | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.952); called by muse, varscan2
- NFIB | c.260A>C p.E87A | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ODF2 | c.1808_1815del p.L603Hfs*7 (on ENST00000434106 / NM_153433.2; = p.L579Hfs*7 on NM_002540.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 21/166 reads (13%) | called by mutect2, pindel, varscan2
- OTOGL | c.3827_3846del p.S1276Ffs*6 (on ENST00000547103; = p.S1267Ffs*6 on NM_173591.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 38/138 reads (28%) | called by mutect2, pindel, varscan2
- PIK3C2A | c.2390A>C p.D797A | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- PIP4K2A | c.965A>G p.N322S | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PKD1L1 | c.1065_1066insC p.F356Lfs*32 | Frame Shift Ins (INS) | VAF 30/125 reads (24%) | called by mutect2, pindel, varscan2
- PTEN | c.938_974del p.K313Mfs*19 | Frame Shift Del (DEL) | VAF 70/182 reads (38%) | called by pindel, varscan2
- PVRIG | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- RAB18 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- RNF135 | c.289_305del p.D97Lfs*101 | Frame Shift Del (DEL) | VAF 46/209 reads (22%) | called by mutect2, pindel, varscan2
- ROS1 | c.816_831del p.P273Vfs*24 | Frame Shift Del (DEL) | VAF 11/115 reads (10%) | called by mutect2, pindel
- RTN2 | c.1304T>C p.I435T | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- SSH3 | c.305T>C p.V102A | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- TNRC6A | c.4583T>A p.I1528N | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- UBE3C | c.1329C>G p.V443= | Splice Region (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- VAT1 | c.187A>C p.K63Q | Missense Mutation (SNP) | VAF 88/314 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, varscan2
- ZNF620 | c.107A>T p.Y36F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AQP10 | c.171C>T p.T57= | Silent (SNP) | VAF 22/260 reads (8%) | catalogued as COSV61474613; called by muse, mutect2, varscan2
- BCAS1 | c.78C>T p.N26= | Silent (SNP) | VAF 45/141 reads (32%) | called by muse, mutect2, varscan2
- C16orf70 | c.414T>C p.F138= | Silent (SNP) | VAF 24/71 reads (34%) | called by muse, mutect2, varscan2
- ESPNL | c.2148C>T p.I716= | Silent (SNP) | VAF 22/121 reads (18%) | called by muse, mutect2, varscan2
- FGFBP2 | c.33C>T p.T11= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as rs951064430; called by muse, mutect2, varscan2
- KIF23 | c.222A>C p.S74= | Silent (SNP) | VAF 21/171 reads (12%) | called by muse, mutect2, varscan2
- KIF23 | c.342G>C p.T114= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV99532330; called by muse, mutect2, varscan2
- LUZP1 | c.3159G>T p.G1053= | Silent (SNP) | VAF 9/94 reads (10%) | called by mutect2, varscan2
- NWD2 | c.1437G>T p.R479= | Silent (SNP) | VAF 88/262 reads (34%) | called by muse, mutect2, varscan2
- P2RX4 | c.195G>A p.T65= | Silent (SNP) | VAF 29/264 reads (11%) | catalogued as rs373683458; called by muse, mutect2, varscan2
- PIKFYVE | c.1212A>T p.A404= | Silent (SNP) | VAF 48/193 reads (25%) | called by mutect2, varscan2
- PLXDC1 | c.1461G>T p.S487= | Silent (SNP) | VAF 17/87 reads (20%) | called by muse, mutect2, varscan2
- PTPRD | c.2103C>T p.S701= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as rs756214335; called by muse, mutect2, varscan2
- SLC17A6 | c.837T>A p.R279= | Silent (SNP) | VAF 26/217 reads (12%) | called by muse, mutect2, varscan2
- SQLE | c.192C>T p.A64= | Silent (SNP) | VAF 11/212 reads (5%) | catalogued as COSV99772469; called by muse, mutect2
- TDP2 | c.33G>A p.R11= | Silent (SNP) | VAF 146/417 reads (35%) | catalogued as rs770777577; called by muse, mutect2, varscan2
- TRAPPC6A | c.243G>A p.Q81= (on ENST00000585934 / NM_001270891.2; = p.Q95= on NM_024108.3) | Silent (SNP) | VAF 12/220 reads (5%) | catalogued as rs1168166189; called by muse, mutect2
- ZADH2 | c.324C>T p.G108= | Silent (SNP) | VAF 31/213 reads (15%) | called by muse, mutect2, varscan2
- ABLIM3 | c.335+699A>G | Intron (SNP) | VAF 60/195 reads (31%) | catalogued as rs1299965545; called by muse, mutect2, varscan2
- ARL13B | c.*1787A>C | 3'UTR (SNP) | VAF 48/178 reads (27%) | called by muse, mutect2, varscan2
- C7orf50 | c.130-18162C>T | Intron (SNP) | VAF 12/53 reads (23%) | catalogued as rs1021556199; called by muse, mutect2, varscan2
- CARD9 | c.627+28G>T | Intron (SNP) | VAF 4/26 reads (15%) | called by mutect2, varscan2
- CHIT1 | c.1030-189C>T | Intron (SNP) | VAF 20/312 reads (6%) | catalogued as rs1425328870; called by muse, mutect2
- CLRN1 | c.433+19C>T | Intron (SNP) | VAF 65/237 reads (27%) | called by muse, mutect2, varscan2
- CYBC1 | c.*166C>G | 3'UTR (SNP) | VAF 35/102 reads (34%) | called by mutect2, varscan2
- FICD | c.302-167C>T | Intron (SNP) | VAF 63/212 reads (30%) | called by muse, mutect2, varscan2
- GDAP1L1 | c.*330C>A | 3'UTR (SNP) | VAF 43/200 reads (22%) | called by muse, mutect2, varscan2
- GOLGA8IP | n.60T>C | RNA (SNP) | VAF 22/53 reads (42%) | called by mutect2, varscan2
- LARS2 | c.*1039A>G | 3'UTR (SNP) | VAF 35/119 reads (29%) | called by muse, mutect2, varscan2
- LINC02873 | n.394T>A | RNA (SNP) | VAF 22/111 reads (20%) | called by muse, mutect2, varscan2
- MAX | c.37-15T>G | Intron (SNP) | VAF 51/172 reads (30%) | called by mutect2, varscan2
- RUBCNL | c.1330+1601T>G | Intron (SNP) | VAF 21/104 reads (20%) | called by muse, mutect2, varscan2
- SMTN | c.2603+1103G>C | Intron (SNP) | VAF 50/139 reads (36%) | called by muse, mutect2, varscan2
- XDH | c.-42A>C | 5'UTR (SNP) | VAF 37/272 reads (14%) | called by muse, mutect2, varscan2
